TCGA case TCGA-AO-A03P — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d4c778c-7f77-4f0a-8261-2086accf15fd

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 2,911 days (8.0 years).

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.0 years (19,724 days); Year of diagnosis: 2003; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 26; Micrometastasis present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 98 days; Days to treatment end: 141 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Initial disease status: Recurrent Disease; Days to treatment start: 1,918 days (5.3 years); Days to treatment end: 2,331 days (6.4 years); Prescribed dose: 2.5; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Exemestane; Initial disease status: Recurrent Disease; Days to treatment start: 2,332 days (6.4 years); Days to treatment end: 2,422 days (6.6 years); Prescribed dose: 25; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Recurrent Disease; Days to treatment start: 2,422 days (6.6 years); Days to treatment end: 2,839 days (7.8 years); Prescribed dose: 1500; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 2,451 days (6.7 years); Days to treatment end: 2,822 days (7.7 years); Number of cycles: 27; Treatment dose: 20,050 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Fulvestrant; Initial disease status: Progressive Disease; Days to treatment start: 2,853 days (7.8 years); Days to treatment end: 2,881 days (7.9 years); Number of cycles: 3; Treatment dose: 1,500 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Indeterminate; Treatment anatomic sites: Breast.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 59.3 years (21,646 days); Days to diagnosis: 1,922 days (5.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 59.3 years (21,646 days); Days to diagnosis: 1,922 days (5.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (4 entries)
- Day 1,922 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,922 days (5.3 years).
- Days to follow up: 2,576 days (7.1 years); Disease response: With Tumor.
- Days to follow up: 2,911 days (8.0 years); Disease response: With Tumor.
- Disease response: With Tumor; Timepoint: Follow-up.

Molecular and laboratory tests
- ERBB2 (FISH): 1.7; Cell count: 40; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+; Test value range: 20-29%.
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 4+; Test value range: 90-99%.
- ESR1 (IHC): Positive; Staining intensity value: 4+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 2+; Test value range: 80-89%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 40-49%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 80-89%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A03P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-AO-A03P-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-AO-A03P-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 33; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A03P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A03P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Er IHC score: 4+; Her2 IHC score: 0; Margin status: Close; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 2; Her2 IHC percent positive: <10%; Her2 positivity method text: 3+ POSITIVE; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 1: Tumor status: With tumor; New tumor event surgery: Yes; New tumor event her2 positivity IHC score: 2+; New tumor event her2 positivity method: 3+ POSITIVE; New tumor event her2 signal number: 4.0; New tumor event cent 17 signal number: 2.4; New tumor event cent 17 her2 ratio: 1.7; New tumor event her2 fish define method: RATIO > 2.2; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event surgery: No; New tumor event her2 positivity IHC score: 2+; New tumor event her2 positivity method: 3 Point Scale; New tumor event her2 signal number: 4.0; New tumor event cent 17 signal number: 2.4; New tumor event cent 17 her2 ratio: 1.7; New tumor event her2 fish define method: RATIO >2.2.
- Drug treatment 1: Regimen number: 3; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: EXEMESTANE (AROMASIN); Therapy regimen: Recurrence.
- Drug treatment 4: Regimen number: 1; Pharmaceutical therapy drug name: LETROZOLE (FEMARA); Therapy regimen: Recurrence.
- Drug treatment 5: Regimen number: 5; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Estrogen receptor antagonist in metastatic breast cancer.
- Drug treatment 5, Route of administrations: Route of administration: IM.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,911 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,911 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,922 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A03P-01A-11D-A011-01): tumor purity 0.78, ploidy 4.07, whole-genome doublings 1.
